Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA0E, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA0E-01A (Primary Tumor).

ICDD-3
Seminoma NOS 9061/3
Site @ Testis C62.9
9/3/14

Date of procurement:

Pathohistological diagnosis

Seminoma, left testicle

Material received as urgent biopsy.

A gray-yellow piece, size 2.8:2:1 cm, was received. Histologically, the material was defined as seminoma.

1. A cut testicle with tumor, size 5:3.5:2.5 cm, with 11 cm long funiculus up to 2.5 cm in diameter was received. On testicular cut we see white, irregular tumor 3:2.5:2 cm in size. Histologically, the tumor is made of solid cell clusters with round and oval bright nucleus containing nucleolus and moderately abundant bright to pink cytoplasm and surrounding those seats we see connecting tissue containing abundant lymphocyte clusters. On the edges of the testicle we find individual channels that are histochemically PLAP positive, which corresponds with unclassified intratubular germ cell neoplasia (IGCNU).

The tumor does not infiltrate funiculus nor capsule and is not found within vascular areas.

The tumor is also not present in rete testis.

2. Material received as urgent biopsy

A red sample, 1 cm in diameter, 0.6 cm thick was received. Histologically, the material was defined as seminoma. Histologically, in permanent material we find two separate tumor seats, each 0.4 cm in diameter and they are made of tumor cells described above.

Immunohistochemically, tumor cells are CD117 positive and partially PLAP positive.

Source: NCI Genomic Data Commons file 3195b98d-21c5-4aea-a868-2f75cc289378 (TCGA-ZM-AA0E.42E5710C-CA70-4996-ADAC-D2FA1932B20E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).